MMRF case MMRF_2326 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8d70ba38-4181-4126-92d1-ff43c9d59b55

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 72.1 years (26,347 days); ISS stage: I; Days to last known disease status: 801 days (2.2 years); Days to last follow up: 801 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 203 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 106 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 163 days; Days to treatment end: 163 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 281 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -25 (ECOG 0): M Protein 2.95 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 35.6 mg/dL; Immunoglobulin G 48.7 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 0.21 µg/mL; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 9.4 g/dL; Glucose 4.95 mmol/L.
- Day 57 (ECOG 1): M Protein 0.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.954 mg/dL; Beta 2 Microglobulin 0.21 µg/mL; Hemoglobin 8.74 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 7.48 mmol/L.
- Day 154 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.954 mg/dL; Immunoglobulin G 5.91 g/L; Beta 2 Microglobulin 0.21 µg/mL; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 84 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.08 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 9.35 mmol/L.
- Day 238 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 8.53 g/L; Beta 2 Microglobulin 0.2 µg/mL; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 6.71 mmol/L.
- Day 371 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 6.64 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 0.42 µg/mL; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.56 mmol/L.
- Day 462 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 6.36 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.08 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 4.68 mmol/L.
- Day 525 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 6.69 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.1 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 4.79 mmol/L.
- Day 616 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.33 mg/dL; Immunoglobulin G 6.11 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 6.55 mmol/L.
- Day 707 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.33 mg/dL; Immunoglobulin G 6 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.03 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 6.99 mmol/L.
- Day 801 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Immunoglobulin G 5.84 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.03 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 5.23 mmol/L.

Other clinical attributes
- Day -25: Weight: 91 kg; Height: 182 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2326_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -25 days.
- Sample MMRF_2326_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -25 days.
